Somatic mutation profile of tumor specimen TCGA-55-7281-01A (aliquot TCGA-55-7281-01A-11D-2036-08) from TCGA case TCGA-55-7281, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.8 years (25,870 days).
Specimen TCGA-55-7281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44401e97-e401-47ae-85ed-611e462497e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7281-10A (Blood Derived Normal), aliquot TCGA-55-7281-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f81ec158-a3c2-4ec6-bc47-5bb39e297ad9

The open-access MAF lists 482 somatic variants for this specimen: 375 protein-altering or splice-affecting, 98 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 98, Nonsense Mutation 29, Frame Shift Del 15, Intron 4, Splice Site 4, RNA 3, Frame Shift Ins 3, Splice Region 2, 3'UTR 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.1446T>A p.C482* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | hotspot (GDC flag); catalogued as COSV55761560; called by muse, mutect2, varscan2
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA6 | c.2083G>A p.G695S | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52637120; called by muse, mutect2, varscan2
- AC244197.3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs781916566, COSV61711863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACOT12 | c.1249del p.D417Tfs*10 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs756044212; called by mutect2, pindel, varscan2
- ACSL5 | c.1476+2T>A p.X492_splice (on ENST00000354273; = p.X548_splice on NM_016234.3) | Splice Site (SNP) | VAF 5/74 reads (7%) | catalogued as COSV61129743; called by muse, mutect2
- ADA2 | c.752C>G p.P251R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as CM141991, COSV52830891; called by muse, mutect2, varscan2
- ADAMTS2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.783); catalogued as rs867147371, COSV52370685; called by muse, mutect2, varscan2
- ADAMTS7 | c.2749A>T p.S917C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV66306302, COSV66306544; called by muse, mutect2, varscan2
- ADGRB2 | c.4365G>T p.K1455N | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV57072082; called by muse, mutect2, varscan2
- ADH6 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV52955645; called by muse, mutect2, varscan2
- AGBL1 | c.1457C>A p.T486N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.481); catalogued as COSV66853596; called by muse, mutect2, varscan2
- AKAP1 | c.826C>G p.H276D | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.071); catalogued as COSV58469322; called by muse, mutect2, varscan2
- AKNAD1 | c.1619del p.P540Rfs*18 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV62194700; called by mutect2, pindel, varscan2
- AMBN | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59825672; called by muse, mutect2, varscan2
- AMBRA1 | c.3372G>T p.E1124D (on ENST00000458649 / NM_001367468.1; = p.E1034D on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV54051311; called by muse, mutect2, varscan2
- AMER1 | c.2452G>T p.G818W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57657745; called by muse, mutect2, varscan2
- AMPD1 | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV62415564; called by muse, mutect2, varscan2
- ANK2 | c.4828G>T p.E1610* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV52153666; called by muse, mutect2, varscan2
- ANK2 | c.10096A>T p.T3366S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV52153679; called by muse, mutect2, varscan2
- ANK2 | c.10958C>A p.T3653K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV52153694; called by muse, mutect2, varscan2
- ANO1 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60282906; called by muse, mutect2, varscan2
- ANXA5 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV56638633; called by muse, mutect2
- ANXA5 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487934715; called by muse, mutect2, varscan2
- APLNR | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV57241918; called by muse, mutect2, varscan2
- AQR | c.3030A>T p.E1010D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50031167; called by muse, mutect2, varscan2
- ARHGAP4 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.1); catalogued as COSV63131417; called by muse, mutect2, varscan2
- ARHGAP44 | c.651G>T p.T217= | Splice Region (SNP) | VAF 24/59 reads (41%) | catalogued as COSV52392211; called by muse, mutect2, varscan2
- ARMC3 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV53059189; called by muse, mutect2, varscan2
- ATP13A4 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55067779; called by muse, mutect2, varscan2
- ATP1A2 | c.3057C>A p.Y1019* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV63403086; called by muse, mutect2, varscan2
- ATP7B | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV54436823; called by muse, mutect2, varscan2
- AURKC | c.423G>C p.Q141H (on ENST00000302804 / NM_001015878.2; = p.Q107H on NM_003160.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57137540; called by muse, mutect2, varscan2
- B3GALT5 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58198337, COSV58198657; called by muse, mutect2, varscan2
- BBS2 | c.471G>C p.T157= | Splice Region (SNP) | VAF 21/54 reads (39%) | catalogued as CS114530, CS1414369, CS141766, COSV55325754; called by muse, mutect2, varscan2
- BCAM | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV54301380; called by muse, mutect2, varscan2
- BCHE | c.1341C>A p.Y447* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV52255113; called by muse, mutect2, varscan2
- BCORL1 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV54391115, COSV54392951; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4528C>T p.Q1510* | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as COSV63244558, COSV63247242; called by muse, mutect2, varscan2
- BMP6 | c.1040T>G p.V347G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51663092; called by muse, mutect2
- BRCA1 | c.5245C>T p.P1749S | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as CM030005, COSV58785348; called by muse, mutect2, varscan2
- BRDT | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV62864128; called by muse, mutect2, varscan2
- BRINP3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV66518458; called by muse, mutect2
- C2orf78 | c.498T>A p.Y166* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV68517041; called by muse, mutect2, varscan2
- C7 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV57472577, COSV57472727; called by muse, mutect2
- CACNA1B | c.1691C>A p.A564E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV53120434; called by muse, varscan2
- CACNA1E | c.6056G>T p.R2019L (on ENST00000367573 / NM_001205293.3; = p.R1976L on NM_000721.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62385667, COSV62387530; called by muse, mutect2, varscan2
- CACNA1F | c.4065G>T p.Q1355H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV59903752; called by muse, mutect2, varscan2
- CAPN6 | c.993C>A p.C331* | Nonsense Mutation (SNP) | VAF 242/682 reads (35%) | catalogued as COSV60694383; called by muse, mutect2, varscan2
- CATSPERD | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV67534257; called by muse, mutect2, varscan2
- CCDC120 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV64514993, COSV64515577, COSV64515719; called by muse, mutect2, varscan2
- CCDC88C | c.5250C>A p.Y1750* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57796170; called by muse, mutect2, varscan2
- CCKBR | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.283); catalogued as rs761678173, COSV58100040; called by muse, mutect2, varscan2
- CDC5L | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV65175684; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1384A>T p.K462* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV62573284; called by muse, mutect2, varscan2
- CDR1 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as COSV100983371, COSV65164031; called by muse, mutect2, varscan2
- CEP104 | c.1461A>T p.R487S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV65516707; called by muse, mutect2, varscan2
- CERKL | c.979G>C p.V327L (on ENST00000339098 / NM_001030311.2; = p.V301L on NM_201548.5) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV59205636; called by muse, mutect2, varscan2
- CFAP47 | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV52880836; called by muse, mutect2, varscan2
- CHMP2B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55461639; called by muse, mutect2, varscan2
- CHRNA10 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51702844; called by muse, mutect2, varscan2
- CHST1 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV57322912, COSV57323719; called by muse, mutect2, varscan2
- CKAP5 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56365814; called by muse, mutect2, varscan2
- CLOCK | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV59401122; called by muse, mutect2, varscan2
- CNTN4 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.396); catalogued as COSV68568142; called by muse, mutect2, varscan2
- COG6 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62995412; called by muse, mutect2
- COG6 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); catalogued as COSV62995416; called by muse, mutect2, varscan2
- COL18A1 | c.4909C>A p.R1637S (on ENST00000359759 / NM_130444.3; = p.R1402S on NM_030582.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60587676, COSV60593336; called by muse, varscan2
- COL6A1 | c.2353G>T p.G785C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV62612426; called by muse, mutect2, varscan2
- COLEC12 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs779568214, COSV68369638; called by muse, mutect2, varscan2
- CRIM1 | c.2176A>T p.T726S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV54861675; called by muse, mutect2, varscan2
- CRY2 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV69888326; called by muse, mutect2, varscan2
- CSF2RB | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV53256594; called by muse, mutect2, varscan2
- CSMD2 | c.5799C>A p.F1933L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53897277, COSV53952091; called by muse, mutect2, varscan2
- CSTF2 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63376181; called by muse, mutect2, varscan2
- CTAG2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55994023; called by muse, mutect2, varscan2
- CTNND2 | c.2993G>T p.G998V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58862221, COSV58874910; called by muse, mutect2, varscan2
- CYP27B1 | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1194321036, COSV57348335; called by muse, varscan2
- DCDC1 | c.3286G>C p.E1096Q (on ENST00000597505 / NM_001367979.1; = p.E203Q on NM_020869.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV60305005; called by muse, mutect2, varscan2
- DCLK1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1278196878, COSV55179613; called by muse, mutect2, varscan2
- DCSTAMP | c.1007T>A p.V336D | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52577008; called by muse, mutect2, varscan2
- DGCR2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs777563623, COSV54217688; called by muse, varscan2
- DKC1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 68/282 reads (24%) | catalogued as CM990476, COSV65777254; called by muse, mutect2, varscan2
- DMD | c.4456C>T p.P1486S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.79); catalogued as rs762125605, COSV63744302; called by muse, mutect2, varscan2
- DNAH1 | c.5955G>T p.M1985I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV70227604; called by muse, mutect2, varscan2
- DNAH3 | c.5756G>T p.R1919I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV54512757; called by muse, mutect2, varscan2
- DNAH5 | c.2824A>T p.T942S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54214704; called by muse, mutect2, varscan2
- DNAH7 | c.6955G>T p.A2319S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56757947; called by muse, mutect2, varscan2
- DNAH8 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV59435169; called by muse, mutect2, varscan2
- DOCK2 | c.2142G>T p.M714I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.777); catalogued as COSV56951143; called by muse, mutect2, varscan2
- DOCK9 | c.1640C>T p.A547V (on ENST00000376460 / NM_001366676.2; = p.A548V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV59624316; called by muse, mutect2, varscan2
- DQX1 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.584); catalogued as COSV66353051; called by muse, mutect2, varscan2
- DST | c.20830A>G p.T6944A (on ENST00000361203 / NM_001374722.1; = p.T4641A on NM_015548.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1371340365, COSV55005922; called by muse, mutect2, varscan2
- EIF2S3 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV53406264; called by muse, mutect2, varscan2
- ELOA | c.1294T>A p.S432T | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV69309792; called by muse, mutect2, varscan2
- ELOA2 | c.1866G>A p.M622I | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55296476; called by muse, mutect2, varscan2
- ENPEP | c.2624G>T p.W875L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54448812; called by muse, mutect2, varscan2
- EPHA6 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67566275; called by muse, mutect2, varscan2
- EPHB1 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67656570, COSV67657295; called by muse, mutect2, varscan2
- EPS8L3 | c.1331C>G p.S444C (on ENST00000361965 / NM_133181.4; = p.S414C on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV62609104; called by muse, mutect2, varscan2
- ESPNL | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58033587; called by muse, mutect2, varscan2
- EZH1 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70549005; called by muse, mutect2
- F8 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.356); catalogued as CM123841, COSV64271343; called by muse, mutect2, varscan2
- FAM199X | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55433400; called by muse, mutect2, varscan2
- FETUB | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV54005187; called by muse, mutect2, varscan2
- FKBP6 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs782699236, COSV52719500; called by muse, mutect2, varscan2
- FLCN | c.1567A>T p.K523* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as COSV53258341; called by muse, mutect2, varscan2
- FOXD4 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs754306058, COSV58699305; called by muse, mutect2, varscan2
- FOXN2 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61317590; called by muse, mutect2
- FOXO4 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753147451; called by muse, mutect2, varscan2
- FOXO4 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183185322, COSV100447062; called by muse, mutect2, varscan2
- GBX1 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV52546994, COSV99880826; called by muse, mutect2, varscan2
- GIPC2 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66127678; called by muse, mutect2, varscan2
- GORAB | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV63027667; called by muse, mutect2, varscan2
- GP2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56892842; called by muse, mutect2, varscan2
- GPI | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs781682978, COSV62893676; called by muse, mutect2
- GPR156 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59938947; called by muse, mutect2, varscan2
- GPR162 | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV50589865; called by muse, mutect2, varscan2
- GPR50 | c.1238C>A p.A413D | Missense Mutation (SNP) | VAF 132/505 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); catalogued as rs1479836440, COSV54437944; called by muse, mutect2, varscan2
- GPRASP1 | c.3211C>G p.P1071A | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV64355190; called by muse, mutect2, varscan2
- GPRASP2 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV59990775; called by muse, mutect2, varscan2
- GPX5 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV69079249, COSV69079398; called by muse, mutect2, varscan2
- GRIK1 | c.2284C>A p.Q762K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV58714302; called by muse, mutect2, varscan2
- GRM4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs374647710; called by muse, mutect2, varscan2
- GSTA1 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948334822, COSV58014890, COSV58016231; called by muse, mutect2, varscan2
- GSTA5 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 48/175 reads (27%) | catalogued as COSV52861842; called by muse, mutect2, varscan2
- GTPBP3 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV61413878; called by muse, mutect2, varscan2
- HAUS2 | c.167T>G p.I56S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV52999407; called by muse, mutect2, varscan2
- HCN1 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57501848; called by muse, mutect2, varscan2
- HEPH | c.2360G>C p.R787T (on ENST00000343002; = p.R520T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57961282; called by muse, mutect2, varscan2
- HERC1 | c.6208G>T p.G2070W | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71246927; called by muse, mutect2, varscan2
- HERC2 | c.9797C>T p.A3266V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV55315940; called by muse, mutect2, varscan2
- HERC2 | c.1975G>C p.V659L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55315969; called by muse, mutect2, varscan2
- HOXB3 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486297; called by muse, mutect2, varscan2
- HUWE1 | c.9331C>G p.R3111G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53340190; called by muse, mutect2
- HYDIN | c.6372C>A p.D2124E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59253393; called by mutect2, varscan2
- IDS | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100558054; called by mutect2, varscan2
- IGF1R | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as rs1394608159, COSV51276019; called by muse, mutect2
- IGFBP3 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as COSV51872171; called by muse, mutect2, varscan2
- IGHV1-18 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs781791847; called by muse, mutect2, varscan2
- IGHV5-51 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1164071496; called by muse, mutect2, varscan2
- IL10RB | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV51614700; called by muse, mutect2, varscan2
- IL21R | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.308); catalogued as COSV61969425; called by muse, mutect2, varscan2
- IMMP2L | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765843300, COSV59226678; called by muse, mutect2, varscan2
- IMMT | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1278755798, COSV54479362; called by muse, mutect2
- INPP1 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59415507; called by muse, mutect2, varscan2
- INTU | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV56538911; called by muse, mutect2, varscan2
- INTU | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV58870504, COSV58871388; called by muse, mutect2, varscan2
- IQGAP3 | c.3329A>T p.E1110V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63250405; called by muse, mutect2, varscan2
- IRX1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769109884, COSV57358688; called by muse, mutect2, varscan2
- ITGA2B | c.716del p.R239Pfs*140 | Frame Shift Del (DEL) | VAF 31/142 reads (22%) | catalogued as COSV52235562; called by mutect2, pindel, varscan2
- ITGA4 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51999052; called by muse, mutect2, varscan2
- KCNJ5 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964542; called by muse, mutect2, varscan2
- KCNT1 | c.1087A>T p.K363* (on ENST00000488444; = p.K382* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV53698927; called by muse, mutect2, varscan2
- KIF19 | c.1552C>A p.L518M | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63429168; called by muse, mutect2, varscan2
- KIF21B | c.2297T>A p.M766K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59755013; called by muse, mutect2, varscan2
- KIF4B | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70528565; called by muse, mutect2, varscan2
- KLHL6 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.535); catalogued as COSV58064829; called by muse, mutect2, varscan2
- KMO | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); catalogued as COSV63805847, COSV63806306; called by muse, mutect2, varscan2
- KPNA4 | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 9/108 reads (8%) | catalogued as COSV62075182; called by muse, mutect2
- KPRP | c.1171T>C p.C391R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV64221329; called by muse, mutect2, varscan2
- KRT34 | c.864G>C p.W288C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67449544; called by muse, mutect2, varscan2
- KRT5 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV52859238, COSV52859932; called by muse, mutect2, varscan2
- KRTAP15-1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV61877253; called by muse, mutect2, varscan2
- KRTAP27-1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV67001075; called by muse, mutect2, varscan2
- L1CAM | c.1634C>A p.P545H | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV62827467; called by muse, mutect2, varscan2
- LATS1 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.145); catalogued as COSV53588589; called by muse, mutect2, varscan2
- LCP1 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59940233; called by muse, mutect2, varscan2
- LILRA4 | c.483G>C p.R161S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as COSV52491198; called by muse, mutect2, varscan2
- LILRB3 | c.1883G>A p.G628E (on ENST00000346401; = p.G616E on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.559); catalogued as COSV54427538, COSV54432543; called by muse, mutect2, varscan2
- LNP1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV67346357; called by muse, mutect2, varscan2
- LPAR4 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV70912412; called by muse, mutect2, varscan2
- LRP1B | c.11441A>T p.D3814V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV67201680; called by muse, mutect2, varscan2
- LRP1B | c.3624C>A p.D1208E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs756987490, COSV67201686; called by muse, mutect2, varscan2
- LRP2 | c.13207A>G p.S4403G | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1331751622, COSV55547420; called by muse, mutect2, varscan2
- LRRC37B | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV58951601; called by muse, mutect2, varscan2
- LRTM1 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as COSV55526833; called by muse, mutect2, varscan2
- LTBP2 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.46); catalogued as COSV56206435; called by muse, mutect2, varscan2
- LTBP4 | c.323T>A p.L108H (on ENST00000308370 / NM_001042544.1; = p.L71H on NM_003573.2) | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV52578848; called by muse, mutect2, varscan2
- LVRN | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs755238594, COSV63496882; called by muse, mutect2, varscan2
- MAGEC2 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV55998680; called by muse, mutect2, varscan2
- MAGEL2 | c.2769G>T p.E923D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV58566273, COSV58566447; called by muse, mutect2, varscan2
- MAPK14 | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57695221; called by muse, mutect2, varscan2
- MCAM | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV50633052; called by muse, mutect2, varscan2
- MCHR2 | c.309del p.P104Lfs*21 | Frame Shift Del (DEL) | VAF 39/134 reads (29%) | catalogued as rs902197100; called by mutect2, pindel, varscan2
- MED12 | c.2419T>G p.L807V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV61335777; called by muse, mutect2, varscan2
- MEPE | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63072319, COSV63074433; called by muse, mutect2, varscan2
- MICAL3 | c.3631G>T p.D1211Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV71588215; called by muse, mutect2, varscan2
- MICAL3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52894873; called by muse, mutect2, varscan2
- MKI67 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV64073551; called by muse, mutect2, varscan2
- MKRN3 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.221); catalogued as COSV58808435, COSV58809349; called by muse, mutect2, varscan2
- MMP17 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62178815; called by muse, varscan2
- MPL | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV65244500; called by muse, mutect2, varscan2
- MRPL2 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as COSV52434572; called by muse, mutect2, varscan2
- MUC16 | c.38413A>T p.T12805S | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.334); catalogued as COSV67456025; called by muse, mutect2, varscan2
- MUC17 | c.13313G>C p.S4438T | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV60284189; called by muse, mutect2, varscan2
- MUC5AC | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV62253631; called by muse, mutect2, varscan2
- MUC5AC | c.14842G>C p.V4948L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as rs1454634701, COSV100611481; called by muse, mutect2, varscan2
- MUS81 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs367647379; called by mutect2, varscan2
- MXRA5 | c.6744G>T p.K2248N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54230146; called by muse, mutect2, varscan2
- MXRA8 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58510248; called by muse, mutect2, varscan2
- MYBPC1 | c.2985G>T p.L995F (on ENST00000550270 / NM_206820.2; = p.L1002F on NM_002465.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62252056; called by muse, mutect2, varscan2
- MYH6 | c.1451A>T p.E484V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62449062; called by muse, mutect2, varscan2
- MYH9 | c.4018T>A p.S1340T | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV53384017; called by muse, mutect2, varscan2
- MYL3 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52767478; called by muse, mutect2, varscan2
- MYO9B | c.4546G>T p.E1516* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as COSV68277014, COSV68278064; called by muse, mutect2, varscan2
- NALCN | c.3556C>G p.Q1186E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51926603; called by muse, mutect2
- NALCN | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV51926611, COSV51958410; called by muse, mutect2
- NAP1L1 | c.964G>C p.A322P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53873925; called by muse, mutect2, varscan2
- NCKAP5 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV58436593, COSV58444914; called by muse, mutect2
- NEMF | c.1744+1G>T p.X582_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as rs1192853302, COSV53590196; called by muse, mutect2, varscan2
- NFKBIZ | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV58199839; called by muse, mutect2, varscan2
- NGF | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65687364; called by muse, mutect2, varscan2
- NOP56 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV61389453; called by muse, mutect2, varscan2
- NOS2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.806); catalogued as rs1487474759, COSV58222771; called by muse, mutect2, varscan2
- NPY2R | c.729del p.W243* | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs1262267393, COSV61527779; called by mutect2, pindel, varscan2
- NUP188 | c.2422C>T p.Q808* | Nonsense Mutation (SNP) | VAF 39/189 reads (21%) | catalogued as COSV65361130; called by muse, mutect2, varscan2
- NWD1 | c.1606C>A p.L536M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60340084; called by muse, mutect2, varscan2
- NWD1 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs769555044, COSV60340097; called by muse, mutect2, varscan2
- OR10G8 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV70908384, COSV70909199; called by muse, mutect2, varscan2
- OR2C1 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV59239908; called by muse, mutect2, varscan2
- OR2D2 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV55056711; called by muse, mutect2, varscan2
- OR2M5 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 73/466 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV63545990; called by muse, mutect2, varscan2
- OR2W3 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV64456501; called by muse, mutect2, varscan2
- OR4A47 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV71444885; called by muse, mutect2, varscan2
- OR4K17 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV59647700; called by muse, varscan2
- OR5T2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV57588498; called by muse, mutect2, varscan2
- OR6K2 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs761748992, COSV62743302; called by muse, mutect2, varscan2
- OR7A5 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as COSV59234391; called by muse, mutect2, varscan2
- OR8H3 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV57908169; called by muse, mutect2, varscan2
- P2RY8 | c.662T>A p.L221* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV67177020; called by muse, mutect2, varscan2
- PAPOLG | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV53181002, COSV53181940; called by muse, mutect2
- PAQR9 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV61417830, COSV61417895; called by muse, mutect2, varscan2
- PCDH15 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.138); catalogued as rs774448079, COSV57284585; called by muse, varscan2
- PCDHA6 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV65350846, COSV65355737; called by muse, mutect2, varscan2
- PDGFC | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56847111; called by muse, mutect2, varscan2
- PER2 | c.2935C>A p.P979T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV54522417; called by muse, mutect2, varscan2
- PKP1 | c.2021A>T p.Q674L | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV55820472; called by muse, mutect2, varscan2
- PML | c.2582G>T p.R861L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV51444348; called by mutect2, varscan2
- PNPLA7 | c.3589G>T p.G1197W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52996715; called by muse, mutect2, varscan2
- POLA1 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV66884961; called by muse, mutect2, varscan2
- PRMT9 | c.1535A>T p.D512V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV59359274; called by muse, mutect2, varscan2
- PSMB10 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.688); catalogued as rs770335398, COSV50452444; called by muse, mutect2, varscan2
- PTPN23 | c.4831G>T p.G1611W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99650872; called by muse, varscan2
- PTPRG | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV55634777; called by muse, mutect2, varscan2
- PUS7L | c.2101G>T p.V701F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61261549; called by muse, mutect2
- PXDNL | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62484019, COSV62486286; called by muse, mutect2, varscan2
- QTRT1 | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51550749, COSV51551559; called by muse, mutect2, varscan2
- RASA3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs370539205; called by muse, mutect2, varscan2
- RBFOX1 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV60944900, COSV60952976; called by muse, mutect2, varscan2
- RBM10 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61308450; called by muse, mutect2, varscan2
- RBM44 | c.1060C>A p.P354T (on ENST00000611254; = p.P988T on NM_001080504.2) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57628318; called by muse, mutect2, varscan2
- RBMX | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57808072; called by muse, mutect2
- RFC3 | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66296565; called by muse, mutect2, varscan2
- RNF34 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV63442187; called by muse, mutect2, varscan2
- ROBO1 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71392831; called by muse, mutect2, varscan2
- RTL9 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 139/590 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV71825472; called by muse, mutect2, varscan2
- RYR2 | c.14569A>G p.I4857V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1085307524, COSV63675482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.4642G>T p.G1548* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV66537609; called by muse, mutect2, varscan2
- SAXO1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV65869550; called by muse, mutect2, varscan2
- SBDS | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1226498367, COSV55887310; called by muse, mutect2
- SBK1 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.599); catalogued as rs769357637, COSV59396660, COSV59398095; called by muse, mutect2, varscan2
- SCFD2 | c.1763G>A p.R588K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV66370387; called by muse, mutect2, varscan2
- SCN3A | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); catalogued as COSV51806006; called by muse, mutect2, varscan2
- SCN5A | c.4292C>T p.S1431F (on ENST00000333535 / NM_198056.3; = p.S1430F on NM_000335.5) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61120144; called by muse, mutect2
- SCN5A | c.1790G>C p.C597S | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV61120159; called by muse, mutect2, varscan2
- SEMA5A | c.1628T>A p.F543Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV66788745; called by muse, mutect2, varscan2
- SEMG2 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); catalogued as COSV65647322; called by muse, mutect2, varscan2
- SERPINA10 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56227862; called by muse, mutect2, varscan2
- SETDB2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV51643832; called by muse, mutect2, varscan2
- SGCZ | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66006197; called by muse, mutect2
- SH3KBP1 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as COSV65646593; called by muse, mutect2, varscan2
- SHROOM3 | c.3723G>T p.R1241S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56026224; called by muse, mutect2, varscan2
- SIRPB1 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53538122; called by muse, mutect2, varscan2
- SLC10A5 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV72828299; called by muse, mutect2, varscan2
- SLC22A14 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56197130; called by muse, mutect2, varscan2
- SLC5A1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1184272183, COSV56684276; called by muse, mutect2, varscan2
- SLC6A13 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV58256363; called by muse, mutect2, varscan2
- SLC6A14 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64146490; called by muse, mutect2, varscan2
- SLC9A7 | c.1391C>A p.S464Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60379060; called by muse, mutect2, varscan2
- SNAP91 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52119231; called by muse, mutect2, varscan2
- SNX31 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV61262543; called by muse, mutect2, varscan2
- SPAG1 | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV52558928; called by muse, mutect2, varscan2
- SPART | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV62084423; called by muse, mutect2, varscan2
- SPATA20 | c.1388T>C p.L463P (on ENST00000356488 / NM_001258372.1; = p.L479P on NM_022827.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV50066197; called by muse, mutect2, varscan2
- SPATA21 | c.1253G>T p.R418M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59186147, COSV59187745; called by muse, mutect2, varscan2
- SPATA31D1 | c.3499G>A p.G1167R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs765637262, COSV61194239; called by muse, mutect2, varscan2
- SPI1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57044591; called by muse, mutect2, varscan2
- SPRR1A | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV61081048, COSV61081231; called by muse, mutect2, varscan2
- SPTB | c.5545G>T p.G1849C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs1384561485, COSV67629963, COSV67630706; called by muse, mutect2, varscan2
- SRGAP1 | c.2291T>G p.F764C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748343534, COSV61896137; called by muse, mutect2, varscan2
- ST3GAL4 | c.891G>T p.E297D (on ENST00000392669 / NM_001254758.1; = p.E293D on NM_006278.3) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.831); catalogued as COSV57106746; called by muse, mutect2, varscan2
- ST8SIA5 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV59330863, COSV59332688; called by muse, mutect2, varscan2
- STARD8 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52923765; called by muse, mutect2, varscan2
- SVEP1 | c.6137A>G p.Y2046C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52837624; called by muse, mutect2, varscan2
- SYN1 | c.399A>T p.K133N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55980556; called by muse, mutect2, varscan2
- SYNE2 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV100647944; called by muse, mutect2, varscan2
- TAF1L | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 42/157 reads (27%) | catalogued as COSV54259988, COSV54271793; called by muse, mutect2, varscan2
- TBX4 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53606166; called by muse, mutect2, varscan2
- TEX14 | c.2649T>A p.S883R (on ENST00000240361 / NM_001201457.2; = p.S877R on NM_031272.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV53614205; called by muse, varscan2
- TFAP2B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53826508; called by muse, mutect2
- TFIP11 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs753731297, COSV53225896, COSV53226114; called by muse, mutect2, varscan2
- TGM6 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52478674; called by muse, mutect2, varscan2
- TGM7 | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71772673; called by muse, mutect2, varscan2
- TIAM1 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV54544043, COSV99735127; called by muse, mutect2, varscan2
- TLR7 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV66123650, COSV66123907; called by muse, mutect2, varscan2
- TMEM131L | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs928908629, COSV53642581; called by muse, mutect2, varscan2
- TMEM145 | c.1063T>A p.Y355N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV56624575, COSV56625887; called by muse, mutect2, varscan2
- TMEM38B | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV65949566; called by muse, mutect2, varscan2
- TNR | c.2707G>T p.V903L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV54877950, COSV99690971; called by muse, mutect2, varscan2
- TNR | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54877961; called by muse, mutect2, varscan2
- TNRC18 | c.3434G>T p.R1145L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs371595450, COSV68164208; called by muse, mutect2, varscan2
- TNRC6A | c.1970A>T p.N657I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59362667; called by muse, mutect2, varscan2
- TOR1B | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52212787; called by muse, mutect2, varscan2
- TRAF2 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56037184; called by muse, mutect2, varscan2
- TRIM68 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56168093; called by muse, mutect2, varscan2
- TRMT9B | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs758376419, COSV71600252; called by muse, mutect2, varscan2
- TRPC4 | c.483G>T p.L161F | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1338086775, COSV58995803; called by muse, mutect2, varscan2
- TRPM7 | c.3364T>A p.Y1122N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57915137; called by muse, mutect2
- TTC21B | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54629087; called by muse, mutect2, varscan2
- TTC37 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV62454265; called by muse, mutect2, varscan2
- TTF1 | c.1927G>T p.G643C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57503173; called by muse, mutect2, varscan2
- TTN | c.100086C>A p.D33362E (on ENST00000591111; = p.D25938E on NM_003319.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | PolyPhen probably damaging (0.996); catalogued as COSV59965151; called by muse, mutect2, varscan2
- TTN | c.26701G>T p.V8901F (on ENST00000591111; = p.V7974F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | PolyPhen possibly damaging (0.563); catalogued as rs746558975, COSV59965229; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TXNDC12 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV65413135; called by muse, mutect2, varscan2
- TXNDC15 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64379451; called by muse, mutect2, varscan2
- UBASH3B | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52492549; called by muse, mutect2, varscan2
- UEVLD | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746750409, COSV55577432; called by muse, mutect2, varscan2
- VSIG4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775339601, COSV66073482; called by muse, mutect2, varscan2
- VWF | c.936C>A p.C312* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV54615675; called by muse, mutect2, varscan2
- WDR45 | c.709C>G p.P237A (on ENST00000376372 / NM_001029896.2; = p.P238A on NM_007075.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as COSV59875763; called by muse, mutect2, varscan2
- WSCD2 | c.1164C>A p.D388E | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54580546; called by muse, mutect2
- XIRP2 | c.5423C>T p.P1808L (on ENST00000628543; = p.P1983L on NM_152381.6) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs866810000, COSV54691080; called by muse, mutect2, varscan2
- XPC | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV53204228; called by muse, mutect2, varscan2
- XYLT1 | c.2317G>T p.G773W | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54481252; called by muse, mutect2, varscan2
- Z83844.2 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60927766; called by muse, varscan2
- ZFHX4 | c.3893C>G p.A1298G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV50649376, COSV50651676; called by muse, mutect2
- ZFP82 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as COSV67565003; called by muse, mutect2, varscan2
- ZHX2 | c.1421A>C p.E474A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV58711589; called by muse, mutect2
- ZNF195 | c.958A>T p.I320F (on ENST00000399602 / NM_001130520.3; = p.I248F on NM_007152.5) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV50002644; called by muse, mutect2, varscan2
- ZNF200 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV67723660; called by muse, mutect2, varscan2
- ZNF264 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54041279, COSV99567225; called by muse, mutect2
- ZNF280A | c.1017C>A p.C339* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as COSV57479999; called by muse, mutect2, varscan2
- ZNF317 | c.405A>T p.K135N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV56108914; called by muse, mutect2
- ZNF473 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.546); catalogued as COSV54522558; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.908T>A p.V303E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV53369411; called by muse, mutect2, varscan2
- ZNF516 | c.2461G>C p.A821P | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV71586858; called by muse, mutect2, varscan2
- ZNF609 | c.1112G>T p.R371I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58581728; called by muse, mutect2, varscan2
- ZNF613 | c.467G>T p.G156V (on ENST00000293471 / NM_001031721.4; = p.G120V on NM_024840.4) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV53271364; called by muse, mutect2, varscan2
- ZNF804A | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV56442175, COSV56442417; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1404C>G p.D468E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX2 | c.840dup p.G281Rfs*23 | Frame Shift Ins (INS) | VAF 39/312 reads (13%) | called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CAMK4 | c.969del p.R324Vfs*7 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- CLCN1 | c.1779dup p.G594Wfs*13 | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- CSNK1G3 | c.180del p.X60_splice | Splice Site (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.886dup p.W296Lfs*60 | Frame Shift Ins (INS) | VAF 9/83 reads (11%) | called by mutect2, pindel, varscan2
- F8 | c.4526_4528delinsAG p.G1509Efs*58 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | called by pindel, varscan2*
- GPRC5C | c.1182_1183delinsC p.A395Qfs*17 (on ENST00000652232; = p.A350Qfs*17 on NM_018653.4) | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by pindel, varscan2*
- HOXD12 | c.159_161del p.T54del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel
- ITGA9 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- KCTD1 | c.412del p.R138Gfs*20 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MSN | c.1096del p.E366Kfs*59 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- OR5T3 | c.251del p.C84Sfs*53 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by pindel, varscan2
- POTEA | c.1348del p.M450Wfs*23 (on ENST00000519951 / NM_001005365.2; = p.M404Wfs*23 on NM_001002920.1) | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by pindel, varscan2
- PRRC2A | c.1112del p.P371Lfs*200 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- PTPN23 | c.4830C>A p.N1610K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RABAC1 | c.532del p.E178Rfs*? | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- RIMS2 | c.3066T>G p.D1022E (on ENST00000666250 / NM_001348490.2; = p.D830E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SLC22A16 | c.1541C>A p.A514D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPATA31E1 | c.2528G>T p.C843F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TRIM48 | c.177del p.W59Cfs*14 | Frame Shift Del (DEL) | VAF 44/176 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.420C>T p.P140= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV54504248; called by muse, mutect2, varscan2
- AFF3 | c.1884G>A p.R628= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV57848642; called by muse, mutect2, varscan2
- ALS2 | c.1821C>T p.S607= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV51885622; called by muse, mutect2, varscan2
- AP4E1 | c.1830C>T p.D610= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV55916108; called by muse, mutect2, varscan2
- ARHGAP15 | c.129C>A p.S43= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV54487692; called by muse, mutect2, varscan2
- ARHGEF6 | c.2025C>A p.G675= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV51688997; called by muse, mutect2, varscan2
- ARHGEF6 | c.1215G>A p.L405= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV51689005; called by muse, mutect2
- ASTL | c.1131T>C p.G377= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV60903842; called by muse, mutect2, varscan2
- ATP5F1B | c.1263C>T p.A421= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV51634211; called by muse, mutect2, varscan2
- BRIP1 | c.60A>G p.K20= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV51996931; called by muse, mutect2, varscan2
- CACNA1I | c.4524C>T p.H1508= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs751321994, COSV60804359; called by muse, mutect2, varscan2
- CDX4 | c.417G>T p.T139= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV65171536, COSV65171591; called by muse, mutect2, varscan2
- CHID1 | c.921G>A p.A307= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs768055754, COSV60258397; called by muse, mutect2, varscan2
- CLEC16A | c.1503G>C p.V501= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV101278453, COSV68498804; called by muse, varscan2
- CLK4 | c.114A>G p.Q38= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV60318162; called by muse, mutect2, varscan2
- COL18A1 | c.2907G>A p.Q969= (on ENST00000359759 / NM_130444.3; = p.Q734= on NM_030582.4) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV62700016; called by muse, mutect2, varscan2
- COL6A2 | c.2155C>A p.R719= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV56002121; called by muse, mutect2, varscan2
- COQ5 | c.81C>T p.L27= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV56018374; called by muse, mutect2, varscan2
- DDX60 | c.2220G>C p.L740= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV67095828; called by muse, mutect2, varscan2
- DEPTOR | c.1011G>T p.A337= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs544954637, COSV53818746; called by muse, varscan2
- DMWD | c.861C>G p.L287= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV52176774, COSV52182262; called by muse, mutect2
- DNAH7 | c.3225C>T p.S1075= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV56757956; called by muse, mutect2, varscan2
- DPYS | c.1401A>T p.P467= | Silent (SNP) | VAF 36/234 reads (15%) | catalogued as COSV60907713; called by muse, mutect2, varscan2
- DROSHA | c.1740G>T p.P580= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60774246; called by muse, mutect2, varscan2
- DSCAML1 | c.1491C>T p.P497= (on ENST00000321322; = p.P437= on NM_020693.4) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58386901; called by muse, mutect2, varscan2
- EIF2AK4 | c.2232C>G p.V744= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV55466819; called by muse, mutect2, varscan2
- ERCC6 | c.915A>T p.P305= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV63388853; called by muse, mutect2, varscan2
- EXOC6B | c.957G>A p.R319= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1190835031, COSV55550054; called by muse, mutect2
- FBLN1 | c.732G>T p.R244= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as COSV53045269, COSV99411120; called by muse, mutect2, varscan2
- FBXL13 | c.1614T>C p.S538= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV57536444; called by muse, mutect2, varscan2
- FDXR | c.969A>T p.A323= (on ENST00000293195 / NM_024417.5; = p.A329= on NM_004110.6) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53111072; called by muse, mutect2, varscan2
- FOXM1 | c.2067T>C p.F689= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1484243734, COSV61205606; called by muse, mutect2, varscan2
- FRAS1 | c.10932G>A p.L3644= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV53600038; called by muse, mutect2
- FSHR | c.1449C>G p.L483= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV58620741, COSV58635594; called by muse, mutect2, varscan2
- GPR25 | c.885G>T p.L295= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100421717, COSV58497853; called by muse, mutect2, varscan2
- GPR50 | c.1572C>A p.A524= | Silent (SNP) | VAF 60/297 reads (20%) | catalogued as COSV54437958; called by muse, mutect2, varscan2
- GRIN1 | c.372C>G p.R124= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV59294029; called by muse, mutect2
- GRIN2A | c.3444G>A p.P1148= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as rs1192386958, COSV58024912, COSV58027288; called by muse, mutect2, varscan2
- HLTF | c.726A>T p.P242= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV59499713; called by muse, mutect2, varscan2
- ICE2 | c.327G>T p.V109= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV55030503; called by muse, mutect2, varscan2
- IGHE | c.1251C>A p.T417= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- ITGA9 | c.582C>T p.C194= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ITIH5 | c.1461C>T p.R487= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53662110; called by muse, mutect2, varscan2
- KLHL4 | c.792G>T p.L264= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV64140509; called by muse, mutect2, varscan2
- KRTAP1-5 | c.213C>T p.C71= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV62624124; called by muse, mutect2, varscan2
- KRTAP19-1 | c.103C>A p.R35= | Silent (SNP) | VAF 84/340 reads (25%) | catalogued as COSV66861122; called by muse, mutect2, varscan2
- LEF1 | c.318C>A p.P106= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54465636, COSV54466818; called by muse, mutect2, varscan2
- LRP1B | c.4002G>T p.L1334= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV67201683; called by muse, mutect2, varscan2
- LRRC55 | c.751C>T p.L251= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV73006415; called by muse, mutect2, varscan2
- MED12L | c.4764C>A p.S1588= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV56373775; called by muse, mutect2, varscan2
- MED14 | c.1302A>T p.A434= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV61356380; called by muse, mutect2, varscan2
- MMP7 | c.492G>T p.G164= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV52771635; called by muse, mutect2, varscan2
- NLRP3 | c.2088C>A p.G696= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60222005; called by muse, mutect2, varscan2
- NPBWR1 | c.669T>C p.Y223= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58695812; called by muse, mutect2, varscan2
- OR10W1 | c.111G>T p.V37= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV67720330; called by muse, mutect2, varscan2
- OR4A16 | c.684G>A p.Q228= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs1355447652, COSV59042460; called by muse, mutect2, varscan2
- OR4D11 | c.585T>A p.L195= | Silent (SNP) | VAF 59/202 reads (29%) | catalogued as COSV57585186; called by muse, mutect2, varscan2
- OR9Q1 | c.666C>A p.I222= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV59038731, COSV59040427; called by muse, mutect2, varscan2
- PCDHA10 | c.1101C>G p.V367= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV56489142, COSV56497707; called by muse, mutect2, varscan2
- PCDHB14 | c.1929G>T p.L643= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs201846722; called by muse, mutect2, varscan2
- PDIA2 | c.723C>G p.G241= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV51985559; called by muse, mutect2, varscan2
- PIGS | c.321C>A p.A107= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as COSV52024000; called by muse, mutect2, varscan2
- PKD2L1 | c.1518T>C p.F506= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs749798302, COSV58395318; called by muse, mutect2, varscan2
- POLD2 | c.618C>T p.G206= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs757035691, COSV56256562; called by muse, mutect2, varscan2
- PRAMEF14 | c.990G>T p.V330= | Silent (SNP) | VAF 72/345 reads (21%) | catalogued as COSV100577287; called by muse, mutect2, varscan2
- PRDM9 | c.663C>A p.P221= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV57004461, COSV57014439; called by muse, mutect2, varscan2
- PTPRC | c.2253C>A p.V751= | Silent (SNP) | VAF 115/386 reads (30%) | catalogued as COSV61408815; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1674G>A p.L558= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs372036662; called by mutect2, varscan2
- RAPGEF6 | c.1428G>A p.R476= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV57243314; called by muse, mutect2, varscan2
- RASA3 | c.2493T>A p.T831= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV61865625; called by muse, mutect2, varscan2
- RC3H2 | c.2451G>T p.A817= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100605309, COSV61799165; called by muse, mutect2, varscan2
- RELB | c.1452C>G p.L484= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV55509305; called by muse, mutect2
- RFX6 | c.750T>A p.L250= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV60584212; called by muse, mutect2, varscan2
- RIT2 | c.348C>T p.L116= | Silent (SNP) | VAF 102/252 reads (40%) | catalogued as COSV56296899; called by muse, mutect2, varscan2
- SCML1 | c.312T>C p.Y104= (on ENST00000380041 / NM_001037540.3; = p.Y77= on NM_006746.6) | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV66240479; called by muse, mutect2, varscan2
- SETBP1 | c.2343A>G p.T781= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV56317384; called by muse, mutect2, varscan2
- SH3PXD2B | c.153C>T p.L51= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV61125755; called by muse, mutect2
- SHROOM4 | c.3216C>T p.A1072= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV56787037; called by muse, mutect2, varscan2
- SLC22A12 | c.18C>G p.L6= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV60571476, COSV60573291; called by muse, mutect2, varscan2
- SLC22A2 | c.849A>T p.I283= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV65265946; called by muse, mutect2
- SLC25A36 | c.660G>T p.V220= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV60781644; called by muse, mutect2, varscan2
- SLC26A3 | c.1086C>A p.S362= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV60638721, COSV60641636; called by muse, mutect2, varscan2
- SLC4A1 | c.2319C>G p.S773= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52259249; called by muse, mutect2, varscan2
- SLC9A7 | c.135G>T p.G45= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV60379070; called by muse, mutect2, varscan2
- SMUG1 | c.261A>T p.G87= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV54538991; called by muse, mutect2, varscan2
- STK11IP | c.2493G>T p.V831= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55247041; called by muse, mutect2, varscan2
- TECPR1 | c.849C>T p.I283= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs770318671, COSV65782976; called by muse, mutect2, varscan2
- TGFBR2 | c.915C>T p.L305= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs146030104, CX120561; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TMEM140 | c.291C>A p.A97= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV51965865; called by muse, mutect2, varscan2
- TMEM63B | c.1794C>G p.L598= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52477920; called by mutect2, varscan2
- TMPRSS7 | c.1608C>A p.L536= (on ENST00000452346; = p.L410= on NM_001042575.2) | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV69980233, COSV69981698; called by muse, mutect2, varscan2
- TPGS2 | c.348C>T p.P116= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV57540111; called by muse, mutect2, varscan2
- TRPM1 | c.144C>T p.T48= | Silent (SNP) | VAF 107/462 reads (23%) | catalogued as COSV56632789; called by muse, mutect2, varscan2
- URI1 | c.273C>T p.V91= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV56348938; called by muse, mutect2, varscan2
- VSX2 | c.651G>T p.A217= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV56216951; called by muse, mutect2, varscan2
- WNK2 | c.3522C>A p.S1174= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52942544; called by muse, varscan2
- WRN | c.2367A>T p.L789= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV53298194; called by muse, mutect2, varscan2
- ZNF746 | c.309G>A p.K103= | Silent (SNP) | VAF 101/201 reads (50%) | catalogued as COSV61406929; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824863 C>A | 5'Flank (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2
- CNTN1 | c.1805-9422T>A | Intron (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- CNTN1 | c.1805-9420T>C | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- HM13 | c.1035-927C>T | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as rs529063036; called by mutect2, varscan2
- OR2W5 | n.483C>A | RNA (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- RALB | c.*1G>T | 3'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99732669; called by muse, varscan2
- RBM44 | c.-98-1980G>T | Intron (SNP) | VAF 24/55 reads (44%) | catalogued as COSV57628299; called by muse, mutect2, varscan2
- SSPOP | n.12012C>T | RNA (SNP) | VAF 15/62 reads (24%) | catalogued as COSV65128498; called by muse, mutect2, varscan2
- WASF4P | n.1067C>A | RNA (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
